Gene-level copy-number profile of tumor specimen BLGSP-71-27-00415-01A from CGCI case BLGSP-71-27-00415, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 68.1 years (24,887 days).
Specimen BLGSP-71-27-00415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f2aa71c7-d4da-4b62-80c7-87100a8b7b5e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-27-00415-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/74a7b62e-7295-468f-bfdf-17bd408a4e49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 229; copy number 1: 5,020; copy number 2: 51,934; copy number 3: 1,276; copy number 4: 396; copy number 5: 23; copy number 6: 2; copy number 24: 1.

Homozygous deletions (total copy number 0; autosomes only): 229 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,403,964–2,413,797, 1 gene (within-gene range 0–1): PEX10.
- chr1:3,021,467–3,736,201, 19 genes (within-gene range 0–2): ACTRT2, PRDM16-DT, PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1, MEGF6, MIR551A, AL513320.1, TPRG1L, WRAP73, TP73, TP73-AS3, TP73-AS2.
- chr1:228,208,044–228,425,360, 12 genes (within-gene range 0–1): OBSCN, AL353593.1, AL353593.2, AL353593.3, AL670729.3, AL670729.2, TRIM11, AL670729.1, MIR6742, AL139288.1, TRIM17, H3-4.
- chr2:2,729,908–2,730,957, 1 gene: AC018685.1.
- chr2:120,319,007–120,351,803, 2 genes: AC012363.2, INHBB.
- chr2:120,735,623–120,992,653, 2 genes: GLI2, AC017033.1.
- chr2:130,129,621–130,182,750, 3 genes (within-gene range 0–1): MED15P9, CCDC74B, SMPD4.
- chr2:130,611,440–130,658,037, 2 genes: POTEJ, RNU6-848P.
- chr2:131,491,160–131,536,988, 4 genes (within-gene range 0–1): MIR4784, SMPD4BP, CCDC74A, MED15P4.
- chr4:3,758,748–3,768,526, 2 genes: LINC02600, ADRA2C.
- chr4:7,965,310–8,241,803, 6 genes: ABLIM2, MIR95, AC097381.3, AC097381.2, GMPSP1, SH3TC1.
- chr4:9,170,409–9,231,233, 6 genes: FAM90A26, USP17L10, USP17L11, USP17L12, USP17L13, USP17L14P.
- chr5:1,005,039–1,295,068, 9 genes: AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:3,595,832–3,601,403, 2 genes: IRX1, AC016595.1.
- chr7:1,428,465–1,467,522, 3 genes: MICALL2, AC102953.1, AC102953.2.
- chr7:56,805,336–57,020,273, 7 genes: CICP28, AC118758.2, AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1.
- chr7:63,326,674–63,354,326, 3 genes (within-gene range 0–2): AC006455.1, ARAFP3, AC006455.6.
- chr7:63,556,598–63,843,505, 8 genes: SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1, AC079355.1, CICP24, AC079355.2, AC092634.5.
- chr7:149,764,182–149,833,979, 2 genes: ZNF467, SSPOP.
- chr8:142,089,827–142,621,064, 11 genes: AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1, ADGRB1, MROH4P, ARC, AP006547.1.
- chr10:132,943,967–133,276,868, 13 genes: LINC01166, LINC01167, LINC01168, ADGRA1, ADGRA1-AS1, RPL5P28, KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8.
- chr12:3,296,202–3,366,122, 2 genes: AC005865.1, LINC02827.
- chr12:132,186,735–132,331,575, 9 genes: LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1.
- chr12:132,424,504–132,585,188, 7 genes: AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763.
- chr14:104,474,678–104,605,647, 3 genes: TMEM179, C14orf180, BX927359.1.
- chr14:105,467,793–105,499,575, 5 genes (within-gene range 0–1): AL928654.2, CRIP2, CRIP1, AL928654.3, TEDC1.
- chr14:105,620,506–105,673,314, 7 genes (within-gene range 0–1): IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–1): IGHEP1.
- chr14:105,785,505–105,845,678, 2 genes (within-gene range 0–1): ATP6V1G1P1, IGHD.
- chr14:105,857,513–105,857,572, 1 gene (within-gene range 0–1): MIR4539.
- chr14:105,858,165–106,001,824, 46 genes (within-gene range 0–1): MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1.
- chr16:33,345,182–33,496,093, 6 genes: AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5.
- chr16:33,907,419–33,937,167, 1 gene: ARHGAP23P1.
- chr16:33,976,039–34,013,830, 3 genes (within-gene range 0–2): AC133561.1, BCAP31P1, AC133561.2.
- chr17:73,641,026–73,643,106, 1 gene (within-gene range 0–2): AC032019.1.
- chr17:79,132,722–79,136,402, 1 gene (within-gene range 0–1): AC021534.1.
- chr18:37,243,776–37,762,131, 4 genes (within-gene range 0–2): AC015961.2, AC090386.1, AC090386.2, AC009899.1.
- chr18:79,576,460–79,589,010, 1 gene: AC068473.3.
- chr19:29,489,775–29,526,948, 2 genes (within-gene range 0–1): AC011474.2, AC011474.4.
- chr20:62,402,236–62,478,594, 5 genes (within-gene range 0–1): AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,745,733–157,820,120, 2 genes, copy number 5: FCRL2, FCRL1.
- chr1:198,597,724–198,598,868, 1 gene, copy number 5: AL157402.1.
- chr2:64,086,353–64,144,420, 2 genes, copy number 5 (within-gene range 3–5): AC012368.2, PELI1.
- chr2:130,515,997–130,528,604, 3 genes, copy number 5: AC013269.2, Metazoa_SRP, CFC1B.
- chr11:9,664,077–9,752,993, 2 genes, copy number 5: SWAP70, RN7SKP50.
- chr14:18,333,726–18,419,273, 3 genes, copy number 5–6: CR383658.1, CR383658.2, BNIP3P6.
- chr14:106,867,660–106,879,812, 3 genes, copy number 5: IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:65,578,753–65,792,293, 6 genes, copy number 5 (within-gene range 3–5): INTS14, SLC24A1, AC011939.3, DENND4A, SNORD13E, MIR4511.
- chr15:65,766,460–65,772,139, 2 genes, copy number 5 (within-gene range 3–5): AC011939.2, AC011939.1.
- chr16:33,802,764–33,810,767, 2 genes, copy number 6–24: IGHV3OR16-12, AC136428.3.

Autosomal genes at a single copy (total copy number 1): 2,164. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
